Somatic mutation profile of tumor specimen 0DGWOL from CCDI case PBBTUV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.1 years (3,328 days).
Specimen 0DGWOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b127ae3e-3acd-4b47-a25f-14a86fa2690c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGWO6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5f89fe3-2beb-48aa-b609-4daf692383ea

The open-access MAF lists 4 somatic variants for this specimen: 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.5790C>T p.G1930= | Silent (SNP) | VAF 21/357 reads (6%) | catalogued as rs368191696, COSV60928459; called by muse, mutect2
- LY75 | c.4065C>T p.D1355= | Silent (SNP) | VAF 28/602 reads (5%) | catalogued as rs752616828; called by muse, mutect2
- SPRN | c.171C>T p.Y57= | Silent (SNP) | VAF 172/495 reads (35%) | catalogued as rs562098774; called by muse, mutect2, varscan2
- ITK | c.986-77T>A | Intron (SNP) | VAF 68/145 reads (47%) | called by muse, mutect2, varscan2
